Somatic mutation profile of tumor specimen TCGA-CR-6470-01A (aliquot TCGA-CR-6470-01A-11D-1870-08) from TCGA case TCGA-CR-6470, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 38.7 years (14,133 days).
Specimen TCGA-CR-6470-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8addc2f9-9690-4fec-bc42-90d7070130a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-6470-10A (Blood Derived Normal), aliquot TCGA-CR-6470-10A-01D-1870-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/34d8cddf-6b7c-41be-ae69-d33e6dee11a1

The open-access MAF lists 36 somatic variants for this specimen: 30 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 25, Silent 6, Frame Shift Del 2, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EP300 | c.4195G>A p.D1399N | Missense Mutation (SNP) | VAF 25/116 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519889, COSV54325045, COSV54326888, COSV54344606; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.2538A>G p.I846M | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as COSV99286519; called by muse, mutect2, varscan2
- ADCY1 | c.2605G>A p.V869I | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs751469911, COSV99811368; called by muse, mutect2, varscan2
- BCAR3 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99551050; called by muse, mutect2, varscan2
- BPIFB1 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV99487554; called by muse, mutect2, varscan2
- BRWD3 | c.1601A>G p.H534R | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100956346; called by muse, mutect2, varscan2
- CATSPERB | c.1133G>A p.R378K | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99831556; called by muse, mutect2, varscan2
- CCDC113 | c.278T>C p.V93A | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99541133; called by muse, mutect2
- CYLD | c.1853A>C p.D618A | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100282646; called by muse, mutect2, varscan2
- CYP4A22 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.232); catalogued as rs143425502; called by muse, mutect2, varscan2
- DAPK3 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100009821; called by muse, mutect2, varscan2
- DNMT1 | c.3988C>T p.P1330S | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100532831; called by muse, mutect2, varscan2
- ERC1 | c.3131G>A p.G1044E (on ENST00000360905 / NM_178040.4; = p.G1016E on NM_178039.4) | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as COSV100705667, COSV100706480; called by muse, mutect2, varscan2
- H4C4 | c.148C>T p.L50F | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.233); catalogued as rs1033729066, COSV100534462; called by muse, mutect2, varscan2
- HEATR1 | c.235C>T p.R79* | Nonsense Mutation (SNP) | VAF 11/79 reads (14%) | catalogued as rs1460626340, COSV100857220; called by muse, mutect2, varscan2
- KMT2E | c.4078C>T p.P1360S | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.146); catalogued as COSV99996718; called by muse, mutect2, varscan2
- LFNG | c.889G>A p.V297M (on ENST00000222725 / NM_001040167.2; = p.V168M on NM_002304.2) | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1201006119, COSV99761892; called by muse, mutect2, varscan2
- NCAPH | c.943A>T p.I315F | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV99546052; called by muse, mutect2, varscan2
- NOTCH3 | c.1678G>A p.V560M | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.667); catalogued as rs200160665, COSV99658247; ClinVar: likely benign; called by muse, mutect2, varscan2
- PTPRJ | c.823C>G p.L275V | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV101395621; called by muse, mutect2, varscan2
- RAB40AL | c.701G>A p.R234K | Missense Mutation (SNP) | VAF 52/107 reads (49%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.248); catalogued as COSV99505213; called by muse, mutect2, varscan2
- RASL10B | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs782005346; called by muse, mutect2, varscan2
- SLC25A22 | c.553G>A p.G185S | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs761249044, COSV100204272; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SVIL | c.3487C>T p.Q1163* (on ENST00000355867 / NM_021738.3; = p.Q737* on NM_003174.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 22/95 reads (23%) | catalogued as COSV100881442; called by muse, mutect2, varscan2
- TTN | c.14972G>A p.R4991Q (on ENST00000591111; = p.R4064Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/120 reads (23%) | PolyPhen possibly damaging (0.69); catalogued as rs146847928, COSV60102722; called by muse, mutect2, varscan2
- UTP25 | c.2210G>A p.R737Q | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs141651647; called by muse, mutect2, varscan2
- ZCCHC2 | c.2138A>C p.Y713S | Missense Mutation (SNP) | VAF 48/250 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV99502581; called by muse, mutect2, varscan2
- HCFC1R1 | c.378dup p.Y127Lfs*61 | Frame Shift Ins (INS) | VAF 5/19 reads (26%) | called by mutect2, pindel
- IPO13 | c.2738_2745del p.F913Cfs*6 | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | called by mutect2, pindel, varscan2
- TTN | c.15710del p.L5237Rfs*2 (on ENST00000591111; = p.L4310Rfs*2 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 33/184 reads (18%) | called by mutect2, pindel, varscan2
- ECT2 | c.1725C>T p.L575= (on ENST00000392692 / NM_001349098.2; = p.L544= on NM_018098.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 12/178 reads (7%) | catalogued as COSV51686575, COSV99221655; called by muse, mutect2
- ENTHD1 | c.150C>G p.L50= | Silent (SNP) | VAF 30/126 reads (24%) | catalogued as rs1230037608, COSV100288983; called by muse, mutect2, varscan2
- FNDC7 | c.1413C>T p.F471= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as rs779919508, COSV99600922, COSV99601529; called by muse, mutect2, varscan2
- LAPTM5 | c.274C>T p.L92= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV53854205; called by muse, mutect2, varscan2
- MACF1 | c.876G>A p.S292= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as rs150686066; called by muse, mutect2, varscan2
- NID1 | c.1314G>T p.V438= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV99937968; called by muse, varscan2
